Surgical pathology report (de-identified scan), TCGA case TCGA-A3-A8OU, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-A8OU-01A (Primary Tumor).

[page 1 of 4]
Patient:

Referring Physician:

Gender: F

Ref#:

Hosp#:

Patient Location:

Date of Service:

Date Received:

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. KIDNEY, RIGHT, PARTIAL NEPHRECTOMY:

- Clear cell renal cell carcinoma.
- Fuhrman nuclear grade 1.
- Tumor size: 3.5 cm.
- Surgical margins free of tumor.

ICD O-3
Carcinoma, clear cell 8310/3
Site @ Kidney NOS 064.9
J4 211114

B. BASE OF TUMOR, BIOPSY:

- Negative for tumor.

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade: Clear cell renal cell carcinoma, Fuhrman nuclear grade 1.

Primary tumor: pT1a.

Regional lymph nodes: pNX.

Distant metastasis: pMX.

Pathologic stage: I.

Lymphovascular invasion: Not identified.

Margin status: R0, closest margin cauterized resection margin at 0.9 cm.

Case #:

Printed:

Page 1

This report continues... (FINAL)

[page 2 of 4]
Patient:

FINAL SURGICAL PATHOLOGY REPORT

Kidney Tumor Staging Information

(data derived from current specimen, staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, Oct 2009)

Procedure: Partial nephrectomy.
Specimen type: Partial nephrectomy.
Specimen laterality: Right.

TUMOR FEATURES:

Tumor size: 3.5 cm.
Tumor focality: Single focus.
Histologic type: Clear cell renal cell carcinoma.
Histologic grade: Fuhrman nuclear grade 1.
Sarcomatoid features: Not identified.
Macroscopic extent of tumor: Limited to kidney.
Microscopic tumor extension: Limited to kidney.

LYMPH NODES: Not performed.

MARGIN EVALUATION:

Distance to closest margin: Cauterized resection margin at 0.9 cm.
Other margins: N/A.

PATHOLOGIC TUMOR STAGING DESCRIPTORS:

Primary tumor: pT1a.
Regional lymph nodes: pNX.
Distant metastasis: pMX.
Margin status: R0, negative.
Pathologic stage: I.

Pathologic findings in non-neoplastic kidney: Interstitial chronic inflammation, focal global glomerulosclerosis.

Additional pathologic findings: N/A.
Comment: N/A.

Case #:

Printed:

Page 2

This report continues... (FINAL)

[page 3 of 4]
Patient:

FINAL SURGICAL PATHOLOGY REPORT

Signed by

Source of Specimen:

- A. Right renal mass
- B. Base of Tumor right

Case #:

Printed:

Page 3

This report continues... (FINAL)

[page 4 of 4]
Patient:

FINAL SURGICAL PATHOLOGY REPORT

Clinical History/Operative Dx:

Right renal mass

Intraoperative Diagnosis:

B. FSB: Base of tumor, biopsy: No tumor seen

The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. The specimen is labeled right renal mass and is received without fixative. It consists of a resection of renal tissue which measures 5 x 4 x 3 cm. The cauterized renal margin is inked blue. The cortical surface of the kidney is bulging and on sectioning there is a thinly encapsulated yellow-tan to pale red slightly lobulated to cavitary appearing mass which measures 3.5 x 3.3 x 3 cm. It grossly is 0.9 cm from the closest renal resection margin. Representative tissue is obtained for genetic studies. Representative sections of the renal mass are submitted in cassette A1-A6.

B. The specimen is labeled base of right tumor and is received without fixative. It consists of a 5 x 4 x 3 cm fragment of tan to reddish brown cauterized tissue. It is submitted for frozen section as FS2. The tissue remaining from frozen section is submitted for permanent section in cassette B1.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. An intradepartmental consultation with was obtained.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Case #:

Printed:

Source: NCI Genomic Data Commons file ad97175b-80fd-444e-bf40-38d4a0ac4d1b (TCGA-A3-A8OU.323027EE-B210-4C54-85F0-D92A099F5629.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).